Somatic mutation profile of tumor specimen 0DRY7U from CCDI case PBCFDI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.9 years (6,545 days).
Specimen 0DRY7U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b09a5299-f32f-4220-9508-1064d199a908.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRY83 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2db312bc-8532-4c8a-87f7-d8c21c459bc5

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Intron 5, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD17 | c.5777C>T p.P1926L | Missense Mutation (SNP) | VAF 306/724 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1349467609; called by muse, mutect2, varscan2
- ARHGEF11 | c.2555G>A p.R852Q | Missense Mutation (SNP) | VAF 200/429 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1336270326; called by muse, mutect2, varscan2
- BMX | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 441/491 reads (90%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1440812318; called by muse, mutect2, varscan2
- BNC1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 606/953 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61758856; called by muse, mutect2, varscan2
- FCRL1 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 315/749 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369514044; called by muse, mutect2, varscan2
- KDM3B | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 225/564 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58689567; called by muse, mutect2, varscan2
- LDB1 | c.613C>T p.R205* (on ENST00000425280 / NM_001321612.2; = p.R169* on NM_003893.5) | Nonsense Mutation (SNP) | VAF 267/356 reads (75%) | catalogued as COSV63288576; called by muse, mutect2, varscan2
- MARK1 | c.1843C>A p.H615N | Missense Mutation (SNP) | VAF 328/755 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100857523; called by muse, mutect2, varscan2
- PIK3C2B | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 244/580 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs372711150; called by muse, mutect2, varscan2
- VAV1 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 308/785 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100409515; called by muse, mutect2, varscan2
- DDX60L | c.3427T>C p.C1143R | Missense Mutation (SNP) | VAF 439/1028 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT2 | c.5842T>G p.Y1948D | Missense Mutation (SNP) | VAF 426/944 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- GSE1 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 122/244 reads (50%) | called by muse, mutect2, varscan2
- ITPR2 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 182/431 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- LDB1 | c.129-1G>A p.X43_splice (on ENST00000425280 / NM_001321612.2; = p.X7_splice on NM_003893.5) | Splice Site (SNP) | VAF 32/472 reads (7%) | called by muse, mutect2
- MBIP | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 284/605 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PLK1 | c.1608+1G>A p.X536_splice | Splice Site (SNP) | VAF 254/562 reads (45%) | called by muse, mutect2, varscan2
- PTEN | c.383del p.K128Rfs*6 | Frame Shift Del (DEL) | VAF 476/552 reads (86%) | called by mutect2, varscan2
- SDAD1 | c.1808A>G p.H603R | Missense Mutation (SNP) | VAF 516/1161 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SPATA31D3 | c.2255G>A p.S752N | Missense Mutation (SNP) | VAF 314/1447 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, varscan2
- ST18 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 278/674 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- AAMP | c.1005C>T p.G335= | Silent (SNP) | VAF 160/397 reads (40%) | called by muse, mutect2, varscan2
- EYS | c.5076G>C p.L1692= | Silent (SNP) | VAF 493/1190 reads (41%) | called by muse, mutect2, varscan2
- IBTK | c.30A>G p.S10= | Silent (SNP) | VAF 317/703 reads (45%) | called by muse, mutect2, varscan2
- MYRF | c.2295G>T p.L765= (on ENST00000278836 / NM_001127392.3; = p.L756= on NM_013279.4) | Silent (SNP) | VAF 257/575 reads (45%) | called by muse, mutect2, varscan2
- POGK | c.600C>T p.Y200= | Silent (SNP) | VAF 70/648 reads (11%) | catalogued as rs538402061, COSV63311801; called by muse, mutect2, varscan2
- ADAD2 | c.560-52C>T | Intron (SNP) | VAF 69/178 reads (39%) | catalogued as rs983820870; called by muse, mutect2, varscan2
- GALT | c.904+90A>C | Intron (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- HSD17B8 | c.53-34C>T | Intron (SNP) | VAF 29/225 reads (13%) | catalogued as rs1467131016; called by muse, mutect2, varscan2
- ISOC2 | c.420-41G>A | Intron (SNP) | VAF 22/55 reads (40%) | catalogued as rs199899925; called by muse, mutect2, varscan2
- LTB | c.208+66C>A | Intron (SNP) | VAF 65/150 reads (43%) | called by muse, mutect2, varscan2
- NKX2-2 | c.*15A>G | 3'UTR (SNP) | VAF 117/258 reads (45%) | called by muse, mutect2, varscan2
